Somatic mutation profile of tumor specimen TCGA-IG-A5S3-01A (aliquot TCGA-IG-A5S3-01A-11D-A28B-09) from TCGA case TCGA-IG-A5S3, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 69.6 years (25,414 days).
Specimen TCGA-IG-A5S3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04964a74-2607-421b-a924-e2e755df666c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A5S3-10A (Blood Derived Normal), aliquot TCGA-IG-A5S3-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17d01c90-4ddb-4386-94e7-4b55b5b1c79d

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 21, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, Splice Region 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 27/34 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- BNC1 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778484158, COSV61758229; called by muse, mutect2, varscan2
- CDH10 | c.129G>T p.R43S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV52587821; called by muse, mutect2, varscan2
- CDH9 | c.2048G>C p.R683T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.281); catalogued as COSV50271655; called by muse, mutect2, varscan2
- COL4A4 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs55948916; called by muse, mutect2, varscan2
- COL4A5 | c.4228C>T p.R1410C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs104886270, CM960393, COSV60377043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSEL | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.937); catalogued as COSV59489633; called by mutect2, varscan2
- DYRK4 | c.622C>G p.R208G | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs750043434, COSV50539024; called by muse, mutect2
- EIF2S3 | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.045); catalogued as COSV53406264; called by muse, mutect2, varscan2
- GRM6 | c.2545C>A p.Q849K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51449511; called by muse, mutect2, varscan2
- GUCY1A2 | c.1736A>G p.H579R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV56485846, COSV56507371; called by muse, mutect2, varscan2
- HAL | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54117423; called by muse, mutect2, varscan2
- HNF4G | c.922T>C p.F308L (on ENST00000354370 / NM_001330561.2; = p.F355L on NM_004133.5) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs1208161485; called by muse, mutect2, varscan2
- HSPG2 | c.8902C>G p.R2968G | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.268); catalogued as rs759625593; called by muse, mutect2, varscan2
- KCNA7 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.275); catalogued as rs531366512, COSV55503984; called by muse, mutect2, varscan2
- KRTAP13-2 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as rs771266402, COSV67762164; called by muse, mutect2, varscan2
- LRRC15 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs552954426, COSV61652061; called by muse, mutect2, varscan2
- NPAS4 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs928557567, COSV100215019; called by muse, mutect2, varscan2
- NYX | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs769075010; called by muse, mutect2
- OR10G8 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs778953302, COSV70908798, COSV70908959; called by muse, mutect2, varscan2
- OR51G2 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs767452142, COSV100432216, COSV58993525; called by muse, mutect2, varscan2
- PDZD2 | c.7429G>A p.V2477M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as rs370676238; called by muse, mutect2, varscan2
- PLG | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs1459884645, COSV51982232; called by muse, mutect2, varscan2
- SCUBE1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs140525929; called by muse, mutect2, varscan2
- SIGLEC1 | c.4465C>T p.H1489Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs1274759154; called by muse, mutect2, varscan2
- TRHDE | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs767303355, COSV53830705; called by muse, mutect2, varscan2
- UBQLN3 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV61163489; called by muse, mutect2, varscan2
- ZNF804B | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1402099743, COSV60843906; called by muse, mutect2, varscan2
- ZNF831 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV64038874; called by muse, mutect2
- ADAM23 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA1C | c.6589G>A p.E2197K (on ENST00000399634 / NM_001167625.1; = p.E2126K on NM_000719.7) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CENPT | c.201+1G>T p.X67_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- CPA1 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF6 | c.359T>A p.I120K | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DDX50 | c.1477C>G p.Q493E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH5 | c.220G>C p.V74L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ESPL1 | c.1687G>T p.E563* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- FTSJ3 | c.289del p.R97Vfs*6 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- H1-1 | c.-8_4del | Translation Start Site (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- KCNJ8 | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KIAA2026 | c.3277C>T p.P1093S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MIOX | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MSH4 | c.1813G>T p.E605* | Nonsense Mutation (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- NOTCH1 | c.911del p.N304Mfs*327 | Frame Shift Del (DEL) | VAF 66/123 reads (54%) | called by mutect2, pindel, varscan2
- PLBD1 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKG2 | c.1157C>A p.T386K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2
- PTPRD | c.2518C>A p.L840I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SAXO1 | c.725A>T p.Q242L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.186); called by muse, mutect2
- SLCO1A2 | c.566T>C p.F189S | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRPK1 | c.1236_1239del p.S413Vfs*4 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by mutect2, pindel, varscan2
- THNSL2 | c.570A>G p.G190= | Splice Region (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- TLR10 | c.1673A>T p.N558I | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ZNF775 | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCC8 | c.4398G>T p.L1466= | Silent (SNP) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- ADAMTS14 | c.1632G>A p.S544= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs749282565; called by muse, mutect2, varscan2
- AWAT1 | c.15G>A p.K5= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- COPS8 | c.576C>T p.P192= | Silent (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- CSMD1 | c.9540C>T p.F3180= (on ENST00000520002; = p.F3179= on NM_033225.6) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs752713861; called by muse, mutect2, varscan2
- DCT | c.873C>T p.D291= | Silent (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2, varscan2
- EGFR | c.3603G>A p.A1201= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs202156403, COSV51766519; called by muse, mutect2, varscan2
- FRYL | c.4131C>A p.G1377= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99978801; called by mutect2, varscan2
- GAS6 | c.534C>T p.F178= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs776379476; called by muse, mutect2, varscan2
- HAUS5 | c.1611C>A p.L537= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as rs746696536; called by muse, mutect2, varscan2
- HMCN1 | c.14376G>T p.G4792= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- HTATIP2 | c.60C>T p.S20= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs775602858; called by muse, mutect2, varscan2
- IL3 | c.393G>A p.T131= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs750120195, COSV57308338; called by muse, mutect2, varscan2
- KCNB1 | c.243C>T p.N81= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs1295557969; ClinVar: likely benign; called by muse, mutect2, varscan2
- MARCO | c.210G>T p.L70= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs765781526, COSV59052774; called by muse, mutect2, varscan2
- MGA | c.7947A>C p.P2649= (on ENST00000219905 / NM_001164273.1; = p.P2440= on NM_001080541.2) | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- RAB3C | c.51C>T p.Y17= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs554866418, COSV51435346; called by muse, mutect2, varscan2
- RIN1 | c.348C>T p.F116= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs760724156, COSV60927470; called by muse, mutect2, varscan2
- SLC36A3 | c.1008C>T p.I336= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs748413637; called by muse, mutect2, varscan2
- TRIM54 | c.1020C>T p.A340= (on ENST00000380075 / NM_187841.3; = p.A382= on NM_032546.4) | Silent (SNP) | VAF 23/94 reads (24%) | catalogued as rs1446537335; called by muse, mutect2, varscan2
- ZDHHC1 | c.228C>T p.H76= | Silent (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- SUSD4 | c.725-5647C>T | Intron (SNP) | VAF 23/33 reads (70%) | called by muse, mutect2, varscan2
